Surgical pathology report (de-identified scan), TCGA case TCGA-KC-A7F6, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Cornell Medical College, specimen TCGA-KC-A7F6-01A (Primary Tumor).

[page 1 of 4]
Patient:
MRN:
DOB:
SEX: Male

SURGICAL PATHOLOGY, COMPREHENSIVE

Status: Final result Not Released

Surgical Pathology

Inquiry:
Fax:

Surgical Pathology Report

Specimen Date:

In Lab Date:

Report Date:

Patient:

CLINICAL INFORMATION:
Prostate cancer.

INTRAOPERATIVE DIAGNOSIS:

A-E. Frozen section diagnosis:

Soft tissue only.

Reported to:

GROSS DESCRIPTION:

A. Received fresh, the specimen is labeled "left anterior lateral mid prostate" and consists of a 0.2 x 0.1 x 0.1 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation. Summary of sections: A1 FSC.

B. Received fresh, the specimen is labeled "left anterior lateral para apical" and consists of a 0.3 x 0.1 x 0.1 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation. Summary of sections: B1 FSC.

C. Received fresh, the specimen is labeled "left posterior apical" and consists of a 0.2 x 0.1 x 0.1 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation. Summary of sections: C1 FSC.

D. Received fresh, the specimen is labeled "left posterior para apical" and consists of a 0.1 x 0.1 x 0.1 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation. Summary of sections: D1 FSC.

E. Received fresh, the specimen is labeled "left anterior apical" and consists of a 0.1 x 0.1 x 0.1 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation.

CGCF ICD-3
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site: Prostate NOS
CG1.9
9/26/13

[page 2 of 4]
Summary of sections: E1 FSC.

F. Received fresh, the specimen is labeled "prostate gland and seminal vesicles", and consists of a 54.3 gram radical prostatectomy specimen including a 6.5 x 4.5 x 4.0 cm prostate, a 4.0 x 1.7 x 0.8 cm left seminal vesicle, a 3.1 x 0.7 x 0.6 cm left vas deferens, a 4.0 x 1.2 x 0.9 cm right seminal vesicle, and a 0.0 x 0.7 x 0.6 cm right vas deferens. The right side of the specimen is inked green and the left side is inked black. The seminal vesicle base, bladder neck and apical margins are shaved and submitted. The prostate is serially sectioned from the apex to base with sections designated from A to F respectively. Section B and D are submitted for research. On sectioning, multiple nodular and cystic areas are seen. The prostate is submitted entirely. Summary of sections: F1-RSV and LSV, F2-anterior base, F3-posterior base, F4-anterior apex, F5-posterior apex, F6-AR (miss ink partially), F7-AL (miss ink partially), F8-CRA (miss ink partially), F9-CRP, F10-CLA (miss ink partially), F11-CLP, F12-ERA, F13-ERP, F14-ELA, F15-ELP, F16-FRA, F17-FRP, F18-FLA, F19-FLP.
(Note: R=Right; L=Left; A=Anterior; P=posterior)

G. Received fresh, the specimen is labeled "pelvic lymph nodes" and consists of a 5.5 x 3.5 x 2.0 cm aggregate of fibroadipose tissue and lymph nodes. 100% submitted. Summary of sections: G1-G3.

H. Received fresh, the specimen is labeled "anterior prostatic fat" and consists of an aggregate of fibroadipose tissue and lymph nodes measuring 4.0 x 2.5 x 1.0 cm. 100% submitted. Summary of sections: H1.

DIAGNOSIS:

- A. Prostate, left anterior, lateral mid, biopsy:
Fibromuscular tissue and nerve.
No prostatic glands or carcinoma identified.
- B. Prostate, left anterior lateral para apical, biopsy:
Fibromuscular tissue and nerve.
No prostatic glands or carcinoma identified.
- C. Prostate, left posterior apical, biopsy:
Fibromuscular tissue and nerve.
No prostatic glands or carcinoma identified.
- D. Prostate, left posterior para-apical, biopsy:
Fibromuscular tissue.
No prostatic glands or carcinoma identified.
- E. Prostate, left anterior apical, biopsy:
Fibromuscular tissue and nerve.
No prostatic glands or carcinoma identified.
- F. Prostate gland and seminal vesicles, radical prostatectomy:
Prostatic adenocarcinoma, Gleason score 7(3+4);
bilateral; organ confined.
Seminal vesicles and all surgical margins are negative for tumor.

Please see staging summary.

Note: Tumor is present in the following sections:
F4-F10.

[page 3 of 4]
G Lymph nodes, pelvis, excision:

Twenty one lymph nodes, negative for metastatic carcinoma (0/21).

H. Soft tissue, anterior prostate, excision:

Two lymph nodes, negative for metastatic carcinoma (0/2).

SYNOPTIC DIAGNOSIS:

Histologic Type:	Adenocarcinoma
(conventional, not otherwise specified)	
	Primary Pattern: Grade 3
	Secondary Pattern: Grade 4
	Total Gleason Score: 7
Tumor Quantitation:	Proportion (percent) of
prostatic tissue involved by tumor: 10%	
Pathologic Staging (pTNM):	pT2c: Bilateral disease
	pN0: No regional lymph
node metastasis	
	Number of regional lymph
nodes examined: 23	
	Number of regional lymph
nodes involved: 0	
	pMX: Distant metastasis
cannot be assessed	
Margins:	Margins uninvolved by
invasive carcinoma	
Extraprostatic Extension:	Absent
Seminal Vesicle Invasion:	Absent
Perineural Invasion:	Present
Venous (Large Vessel) Invasion (V):	Absent
Lymphatic (Small Vessel) Invasion (L):	Absent
Additional Pathologic Findings:	High-grade prostatic
intraepithelial neoplasia (PIN)	
	Inflammation: acute and
chronic inflammation	
	Benign prostatic
hyperplasia	

** Electronically Signed Out **

Attending Pathologist

The attending pathologist whose signature appears on this report has reviewed the diagnostic slides, and has edited the gross and microscopic portions of the report in rendering the final diagnosis.

ICD9 Codes: A-H; 185

Billing Codes: A-E;

(Inpatient)

F;

G-H;

SNOMED:

Slides: A-1; B-1; C-1; D-1; E-1; F-22; G-3; H-1

Resulting Agency

Specimen Collected:

Last Resulted:

[page 4 of 4]
Order Information Lab Collection Information, Order Information, Order Providers

Criteria	hw 8/28/13	Yes	No

Source: NCI Genomic Data Commons file 8a8a8c16-3c6e-42e5-9933-d9701d8a13b7 (TCGA-KC-A7F6.357EC50A-622F-4757-A044-7E38A12421FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).